Somatic mutation profile of tumor specimen TCGA-DM-A0XD-01A (aliquot TCGA-DM-A0XD-01A-12D-A152-10) from TCGA case TCGA-DM-A0XD, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,966 days).
Specimen TCGA-DM-A0XD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cce934a5-95a9-4cdb-ae7c-ef58098c460a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A0XD-10A (Blood Derived Normal), aliquot TCGA-DM-A0XD-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c84ccdb4-6b13-47cf-b401-18cbe36bfdc8

The open-access MAF lists 179 somatic variants for this specimen: 133 protein-altering or splice-affecting, 44 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 44, Frame Shift Del 6, Splice Site 6, Nonsense Mutation 5, Splice Region 2, Frame Shift Ins 2, 3'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>A p.Y935* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.11186C>T p.P3729L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs775971666, COSV62092245, COSV62107204; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 163/330 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 137/404 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTA1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as COSV64204146; called by muse, mutect2, varscan2
- ADAMTS12 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745725544, COSV61280531; called by muse, mutect2, varscan2
- ADAMTS7 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs761326054, COSV66309505; called by muse, mutect2, varscan2
- AMPH | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57757918; called by muse, mutect2, varscan2
- APC | c.4337del p.A1446Vfs*27 | Frame Shift Del (DEL) | VAF 62/188 reads (33%) | catalogued as COSV104439195, COSV57383896; called by mutect2, pindel, varscan2
- ARHGEF7 | c.1739C>T p.T580M (on ENST00000375741 / NM_001113511.2; = p.T402M on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as rs764936081, COSV54552020; called by muse, mutect2, varscan2
- ARSF | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 85/108 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63841109; called by muse, varscan2
- ARSF | c.161+2T>A p.X54_splice | Splice Site (SNP) | VAF 50/100 reads (50%) | catalogued as COSV63841113; called by muse, varscan2
- ASB7 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.857); catalogued as rs955385433, COSV58404648; called by muse, mutect2, varscan2
- ATP1A4 | c.1623G>C p.M541I | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV63628618; called by muse, mutect2, varscan2
- BABAM1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375274426; called by muse, mutect2, varscan2
- C2CD6 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755545979, COSV53799114; called by muse, mutect2, varscan2
- CACNA1D | c.3955C>T p.R1319C (on ENST00000350061 / NM_001128840.3; = p.R1339C on NM_000720.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193002808, COSV55448799; called by muse, mutect2, varscan2
- CACNA1E | c.4466C>T p.A1489V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV62425898; called by muse, mutect2, varscan2
- CACNA2D3 | c.1089G>T p.Q363H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55583439; called by muse, mutect2, varscan2
- CACNB1 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV60000308; called by muse, mutect2, varscan2
- CCDC88A | c.4845A>C p.Q1615H (on ENST00000436346 / NM_001365480.1; = p.Q1587H on NM_018084.5) | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55070335; called by muse, mutect2, varscan2
- CDH18 | c.2170G>C p.D724H | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56962282; called by muse, mutect2, varscan2
- CDKL3 | c.1323G>A p.M441I | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99527448; called by muse, mutect2, varscan2
- CLIC6 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1462564399, COSV62449621; called by muse, mutect2, varscan2
- CNTN5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as rs577962852, COSV54312220; called by muse, mutect2, varscan2
- CNTNAP4 | c.3211G>T p.A1071S | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.681); catalogued as COSV56700922; called by muse, mutect2, varscan2
- COL14A1 | c.4316G>A p.R1439K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs200065784; called by muse, mutect2, varscan2
- COL14A1 | c.4317A>G p.R1439= | Splice Region (SNP) | VAF 41/111 reads (37%) | catalogued as COSV52869230; called by muse, mutect2, varscan2
- COL16A1 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as rs202028129, COSV54701914, COSV54714178; called by muse, mutect2, varscan2
- COL4A6 | c.4201G>A p.G1401S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57878745; called by muse, mutect2, varscan2
- COLQ | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201507876, COSV67526108; called by muse, mutect2, varscan2
- CREB5 | c.1286C>A p.A429D (on ENST00000357727 / NM_182898.4; = p.A422D on NM_004904.3) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100743824; called by muse, mutect2, varscan2
- CSMD2 | c.5743C>T p.P1915S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53951391, COSV53965048; called by muse, mutect2, varscan2
- CTRL | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs989280634, COSV52125035; called by muse, mutect2, varscan2
- CYLC2 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 151/453 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs772088258, COSV66338366, COSV66339688; called by muse, mutect2, varscan2
- DIS3L2 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs201189209, COSV99805000; called by muse, mutect2, varscan2
- DNHD1 | c.13220G>A p.R4407Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs749654377, COSV54443610; called by muse, mutect2, varscan2
- EIF2AK1 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 41/162 reads (25%) | catalogued as rs1562752012, COSV52243258; called by muse, mutect2, varscan2
- ERLIN2 | c.46T>G p.C16G | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs368897065; called by muse, mutect2, varscan2
- FAM102A | c.847C>T p.R283W (on ENST00000373095 / NM_001035254.3; = p.R141W on NM_203305.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs762022952, COSV100305312; called by mutect2, varscan2
- FAT4 | c.14622A>C p.Q4874H | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58672325, COSV58674006, COSV58679733; called by muse, mutect2, varscan2
- FBXW7 | c.1313C>T p.S438F (on ENST00000281708 / NM_001349798.2; = p.S358F on NM_018315.5) | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55917612, COSV55942322; called by muse, mutect2, varscan2
- FKBP10 | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387678; called by muse, mutect2
- FOXC2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234048; called by muse, mutect2, varscan2
- FOXRED1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs771128237, COSV55005485; called by muse, mutect2, varscan2
- FYB1 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV60956460; called by muse, mutect2, varscan2
- GABPA | c.802+1G>A p.X268_splice | Splice Site (SNP) | VAF 163/606 reads (27%) | catalogued as rs768673859, COSV61395735, COSV61397285; called by muse, mutect2, varscan2
- GLI3 | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746798261, COSV67886970; called by muse, mutect2, varscan2
- GPC6 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65506295, COSV65538971; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 81/216 reads (38%) | catalogued as COSV57133862; called by muse, mutect2, varscan2
- HPSE | c.116T>A p.V39E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs769348375, COSV60988880; called by muse, mutect2, varscan2
- HSPA2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV99904656; called by muse, mutect2, varscan2
- HTR1A | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.744); catalogued as COSV60503016; called by muse, mutect2, varscan2
- IGFL1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV71443702; called by muse, mutect2, varscan2
- IRX6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs200259402, COSV51862362; called by muse, mutect2, varscan2
- JAK2 | c.1920G>C p.K640N | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67678358; called by muse, mutect2, varscan2
- KCNH1 | c.2392G>A p.V798I (on ENST00000271751 / NM_172362.3; = p.V771I on NM_002238.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs761754626, COSV55085456; called by muse, mutect2, varscan2
- KCNJ4 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs111561943, COSV57858874; called by muse, mutect2, varscan2
- KCNK4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100107581, COSV60454319; called by muse, mutect2, varscan2
- KIF3A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66416597; called by muse, mutect2, varscan2
- KRT13 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV55841544; called by muse, mutect2, varscan2
- MAGEC1 | c.2885G>A p.G962D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53581912; called by muse, mutect2, varscan2
- MDGA1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs546191944, COSV51801988; called by muse, mutect2, varscan2
- MLEC | c.650-1G>A p.X217_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV57330394; called by muse, mutect2, varscan2
- MORC4 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV55246695; called by muse, mutect2, varscan2
- MORN1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763596201, COSV66007396; called by muse, mutect2, varscan2
- MOV10L1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760413650, COSV53171565; called by muse, mutect2, varscan2
- MSL3 | c.1058G>A p.R353H (on ENST00000312196 / NM_078629.4; = p.R187H on NM_006800.4) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56491941, COSV56494290; called by muse, mutect2, varscan2
- MST1R | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs541003810, COSV56572511; called by muse, mutect2, varscan2
- NCOA2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs745769277, COSV71764211, COSV71765023; called by muse, mutect2, varscan2
- NPTX2 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569932192, COSV55716820, COSV55717396, COSV99675047; called by muse, mutect2, varscan2
- NRXN1 | c.2373C>A p.S791= | Splice Region (SNP) | VAF 54/194 reads (28%) | catalogued as COSV58495000; called by muse, mutect2, varscan2
- NSD1 | c.6430G>A p.A2144T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs761103348, COSV61773460, COSV99053189; called by muse, mutect2, varscan2
- NUDT18 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV57160670; called by muse, mutect2, varscan2
- OR4K13 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs777987818, COSV59860913; called by muse, mutect2, varscan2
- OR52I1 | c.429A>C p.Q143H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs536139106, COSV100331576; called by muse, mutect2, varscan2
- OTOGL | c.1336G>A p.G446S (on ENST00000547103; = p.G437S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs200388065; called by muse, mutect2, varscan2
- PAFAH2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs148490669; called by muse, mutect2, varscan2
- PBRM1 | c.3691G>A p.G1231R (on ENST00000296302 / NM_001366071.2; = p.G1206R on NM_018313.5) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1311960562, COSV56297143, COSV56309324; called by muse, mutect2, varscan2
- PCDH10 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52102266, COSV99994165; called by muse, mutect2, varscan2
- PCDHA12 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV56547382; called by muse, mutect2, varscan2
- PCDHGA5 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); catalogued as rs776739278, COSV53982015; called by muse, mutect2, varscan2
- PCLO | c.11424G>T p.R3808S | Missense Mutation (SNP) | VAF 178/278 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433514, COSV61667299; called by muse, mutect2, varscan2
- PHF20L1 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as COSV55198664; called by muse, mutect2, varscan2
- PIK3C2G | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV99848663; called by muse, mutect2, varscan2
- PKDREJ | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53553343; called by muse, mutect2, varscan2
- POSTN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV65714736; called by muse, mutect2, varscan2
- PRKCG | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1222412936, COSV54732288; called by muse, mutect2, varscan2
- PRKG2 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV52332296; called by muse, mutect2, varscan2
- PTCHD4 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749018655, COSV59797550; called by muse, mutect2, varscan2
- PXDNL | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs768124415, COSV62479981, COSV62493818; called by muse, mutect2, varscan2
- RNPEPL1 | c.1289-1G>A p.X430_splice | Splice Site (SNP) | VAF 17/41 reads (41%) | catalogued as COSV54374055; called by muse, mutect2, varscan2
- ROBO2 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59940040; called by muse, mutect2, varscan2
- RYR2 | c.8998G>C p.E3000Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100767127, COSV63696359; called by muse, mutect2, varscan2
- S1PR1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs7549921, COSV100541566, COSV59514589; called by muse, mutect2, varscan2
- SAGE1 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 160/282 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs781819525, COSV61018218; called by muse, mutect2, varscan2
- SALL1 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV99171472; called by muse, mutect2, varscan2
- SLC17A9 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373281234, COSV64848037; called by muse, mutect2, varscan2
- SOX9 | c.686-1G>A p.X229_splice | Splice Site (SNP) | VAF 88/305 reads (29%) | catalogued as COSV55426224; called by muse, mutect2, varscan2
- SPANXD | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 153/784 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs373150100, COSV65152575; called by muse, varscan2
- SPARCL1 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV56806212; called by muse, mutect2, varscan2
- SPTBN4 | c.4338C>G p.N1446K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100149662; called by muse, mutect2
- SRCAP | c.8815C>T p.R2939* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV52681436; called by muse, mutect2, varscan2
- ST6GAL2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | PolyPhen benign (0.155); catalogued as rs200325346, COSV62415927; called by muse, mutect2, varscan2
- STAG1 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 73/189 reads (39%) | catalogued as COSV52624323; called by muse, mutect2, varscan2
- TENM3 | c.3707G>A p.R1236H | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.98); catalogued as rs367732296; called by muse, mutect2, varscan2
- TLE6 | c.470A>T p.D157V (on ENST00000246112 / NM_001143986.2; = p.D34V on NM_024760.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99857844; called by muse, mutect2, varscan2
- TMPRSS11A | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs140937812, COSV58358422, COSV58360724; called by muse, mutect2, varscan2
- TP53 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2
- TRIP12 | c.1843-1G>T p.X615_splice | Splice Site (SNP) | VAF 194/661 reads (29%) | catalogued as COSV52273063; called by muse, mutect2, varscan2
- TRPA1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100082777; called by muse, mutect2, varscan2
- TTN | c.32942A>G p.E10981G (on ENST00000591111; = p.E10054G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/148 reads (35%) | PolyPhen benign (0.275); catalogued as COSV60358194; called by muse, mutect2, varscan2
- UBAC2 | c.38C>T p.A13V (on ENST00000403766 / NM_001144072.2; = p.R55C on NM_177967.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs550310299, COSV63121800; called by mutect2, varscan2
- UNC13A | c.3317G>A p.R1106H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs568021947, COSV53202795; called by muse, mutect2, varscan2
- UNC13C | c.5231T>C p.F1744S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52926043; called by muse, mutect2, varscan2
- WDR3 | c.2738G>A p.S913N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs137952009; called by muse, mutect2, varscan2
- ZFHX3 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201721439, COSV51736642; called by muse, mutect2, varscan2
- ZIC4 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV101267777; called by muse, mutect2, varscan2
- ZMYND8 | c.3089A>T p.N1030I (on ENST00000311275 / NM_001363741.2; = p.N1004I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53696443; called by muse, mutect2, varscan2
- ZNF429 | c.1602G>C p.E534D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV61919181; called by muse, mutect2, varscan2
- ZNF479 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV58643755; called by muse, mutect2, varscan2
- ZNF479 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 180/357 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58639221; called by muse, mutect2, varscan2
- ZNF578 | c.796A>C p.K266Q | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV69737661; called by muse, mutect2, varscan2
- ZNF622 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs777954248, COSV58075300; called by muse, mutect2, varscan2
- ZNF646 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56219361; called by muse, mutect2, varscan2
- ZNF710 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV51565819; called by muse, varscan2
- ARID1A | c.1337_1338del p.S446Lfs*176 | Frame Shift Del (DEL) | VAF 78/290 reads (27%) | called by pindel, varscan2
- CNTNAP4 | c.1970del p.F657Sfs*42 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | called by mutect2, pindel, varscan2
- CUBN | c.8880_8884del p.L2960Ffs*41 | Frame Shift Del (DEL) | VAF 51/145 reads (35%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1212del p.V405Ffs*10 (on ENST00000281708 / NM_001349798.2; = p.V325Ffs*10 on NM_018315.5) | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- HSPA8 | c.1704_1705del p.K569Dfs*6 | Frame Shift Del (DEL) | VAF 61/228 reads (27%) | called by mutect2, pindel, varscan2
- PPM1K | c.750dup p.Q251Afs*20 | Frame Shift Ins (INS) | VAF 77/258 reads (30%) | called by mutect2, pindel, varscan2
- SLC12A2 | c.3509_3510dup p.P1171Sfs*18 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.474C>T p.V158= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1363417062, COSV51105857; called by muse, mutect2, varscan2
- ARSB | c.1107G>A p.K369= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV53729552, COSV53730295; called by muse, mutect2, varscan2
- BATF | c.333C>T p.H111= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs748110657, COSV99708653; called by muse, mutect2
- BLM | c.3039T>C p.H1013= | Silent (SNP) | VAF 83/252 reads (33%) | catalogued as rs747406569, COSV61927553; ClinVar: likely benign; called by muse, mutect2, varscan2
- C3 | c.4827C>T p.S1609= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs150537373; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CFHR5 | c.1347T>C p.C449= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV56828611; called by muse, mutect2, varscan2
- CHRNB2 | c.975G>A p.S325= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs764562633, COSV63809499; called by muse, mutect2, varscan2
- CNGB1 | c.375G>A p.P125= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1406243873, COSV51904688; called by muse, mutect2, varscan2
- COPS7A | c.675A>G p.A225= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs1010286935, COSV57527398; called by muse, mutect2, varscan2
- CSPG4 | c.2931C>T p.S977= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs150737913; called by muse, mutect2, varscan2
- DNAH5 | c.9705C>T p.N3235= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs770064361, COSV54237513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA5 | c.834C>T p.A278= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs780375523, COSV56637499; called by muse, mutect2, varscan2
- F13A1 | c.1191C>T p.D397= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1296404384, COSV53568000; called by muse, mutect2, varscan2
- GAS7 | c.588C>T p.T196= (on ENST00000432992 / NM_201433.2; = p.T56= on NM_003644.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs772183594, COSV60440569; called by muse, mutect2, varscan2
- HHIPL2 | c.657C>T p.P219= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV58567997; called by muse, mutect2, varscan2
- ITPR2 | c.2298G>A p.S766= | Silent (SNP) | VAF 59/98 reads (60%) | catalogued as rs745841899, COSV101189800, COSV67276374; called by muse, mutect2, varscan2
- ITSN1 | c.4743C>T p.R1581= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs148797721; called by muse, mutect2, varscan2
- JPH2 | c.168C>T p.S56= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs748126772, COSV60698037; called by muse, mutect2, varscan2
- KRT8 | c.285C>A p.I95= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV53179336; called by muse, mutect2, varscan2
- LHFPL5 | c.564C>T p.D188= | Silent (SNP) | VAF 59/79 reads (75%) | catalogued as rs1271294036, COSV64178773; called by muse, mutect2, varscan2
- LPAR2 | c.243G>A p.A81= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs759419632, COSV99179059, COSV99179317; called by muse, mutect2, varscan2
- LRP1 | c.5556C>T p.V1852= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1485817610, COSV54526512; called by muse, mutect2, varscan2
- MAGEE2 | c.801G>A p.L267= | Silent (SNP) | VAF 33/238 reads (14%) | catalogued as COSV100972972, COSV64898554; called by muse, mutect2, varscan2
- MAPK4 | c.405C>T p.R135= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs370089598; called by muse, mutect2, varscan2
- MAST4 | c.4068C>T p.P1356= (on ENST00000403625 / NM_001164664.2; = p.P1167= on NM_015183.3) | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55142515; called by muse, mutect2, varscan2
- MMP25 | c.312G>T p.R104= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs143114141; called by muse, mutect2, varscan2
- NEUROG1 | c.408C>T p.F136= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as COSV59081657; called by muse, mutect2, varscan2
- PACS2 | c.2130G>A p.P710= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs782232270, COSV57654395; called by muse, mutect2, varscan2
- PCDH17 | c.1548C>T p.I516= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV64979440; called by muse, mutect2, varscan2
- PCDHGA12 | c.750C>T p.S250= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs774558486, COSV52749810, COSV99337806; called by muse, mutect2, varscan2
- RABEP2 | c.1284G>A p.A428= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs777877547, COSV100707205, COSV62870549; called by muse, mutect2, varscan2
- RSF1 | c.3624G>A p.R1208= | Silent (SNP) | VAF 68/242 reads (28%) | catalogued as COSV57845928; called by muse, mutect2, varscan2
- SEMA5A | c.2796G>A p.G932= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV66805953; called by muse, mutect2, varscan2
- SLITRK5 | c.1896G>A p.A632= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs779169011, COSV61526359; called by muse, mutect2, varscan2
- SMPD3 | c.222G>A p.S74= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs766503967, COSV54716185; called by muse, mutect2, varscan2
- SV2A | c.1473C>T p.R491= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as rs782094239, COSV64965958; called by muse, mutect2, varscan2
- TMCO5A | c.18G>A p.L6= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV60466083; called by muse, mutect2, varscan2
- TMEM129 | c.111G>C p.L37= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1241208595, COSV100304907; called by muse, mutect2, varscan2
- TMEM45A | c.229C>T p.L77= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as COSV60256035; called by muse, mutect2, varscan2
- USP7 | c.682C>T p.L228= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100783907; called by muse, mutect2, varscan2
- WDR41 | c.507C>T p.S169= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as rs753996694, COSV99689003; called by muse, mutect2, varscan2
- ZFPL1 | c.81C>T p.C27= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV51871279; called by muse, mutect2, varscan2
- ZNF710 | c.594C>G p.G198= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV51565808; called by muse, varscan2
- ZNF77 | c.177C>T p.D59= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs770342384, COSV58822674; called by muse, mutect2, varscan2
- KNOP1P1 | n.196C>T | RNA (SNP) | VAF 13/83 reads (16%) | catalogued as rs756216426; called by muse, mutect2, varscan2
- MYL3 | chr3:46833667 C>T | 3'Flank (SNP) | VAF 23/53 reads (43%) | catalogued as rs750666652, COSV70134118; called by muse, mutect2, varscan2
